Gene-level copy-number profile of specimen HCM-CSHL-0372-C25-85A from HCMI case HCM-CSHL-0372-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,632 days).
Specimen HCM-CSHL-0372-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8716bb3e-3580-451e-8b28-e73b2f0ae37c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0372-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/3f8a5862-1c81-4a92-a15f-e511fd92db46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 9,139; copy number 2: 46,927; copy number 3: 2,303.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,760,088–42,129,510, 5 genes: AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P.
- chr9:64,369,394–65,193,610, 19 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12.
- chr9:66,253,424–66,254,464, 1 gene: CDRT15P12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
